Somatic mutation profile of tumor specimen MP2PRT-PAPWCD-TMP1-A (aliquot MP2PRT-PAPWCD-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPWCD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,576 days).
Specimen MP2PRT-PAPWCD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac0f7add-f03f-4eb4-a678-72e3da153561.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPWCD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPWCD-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a972aebe-1ac0-4da9-8d9b-65d6a5c6e699

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNP | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 195/461 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs1555643290, COSV66368095; called by muse, mutect2, varscan2
- GPC5 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 208/454 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- ZNF570 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 198/479 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- BOP1 | c.1902C>T p.N634= | Silent (SNP) | VAF 176/391 reads (45%) | catalogued as rs938032796; called by muse, varscan2
- HGS | c.972T>C p.P324= | Silent (SNP) | VAF 185/370 reads (50%) | called by muse, varscan2
- MUC16 | c.27513G>A p.S9171= | Silent (SNP) | VAF 230/487 reads (47%) | catalogued as rs372068481; called by muse, mutect2, varscan2
